Gene-level copy-number profile of tumor specimen ALCH-B1MI-TTP1-A from ALCHEMIST case ALCH-B1MI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.6 years (23,601 days).
Specimen ALCH-B1MI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 86960b24-c484-4a30-bcb4-ccb12d411409.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1MI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,274 have no estimate.
https://portal.gdc.cancer.gov/files/1411d366-e0d1-45b5-bd4a-eb5ae3e56aff

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,249; copy number 2: 54,323; copy number 3: 2,139; copy number 4: 409; copy number 5: 120; copy number 6: 61; copy number 7: 23; copy number 8: 8; copy number 9: 12; copy number 14: 2; copy number 38: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 229 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:1,005,039–1,295,068, 9 genes, copy number 5: AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT.
- chr7:75,156,639–75,410,996, 14 genes, copy number 9–14 (within-gene range 3–14): NCF1C, GTF2IP1, PHBP6, AC211486.5, AC211486.2, AC211486.4, SPDYE13, PMS2P10, Y_RNA, SPDYE14, AC211486.3, Y_RNA, AC211486.1, TRIM73.
- chr9:67,512,034–67,515,393, 1 gene, copy number 6: BX664730.1.
- chr9:115,888,169–116,012,965, 2 genes, copy number 5: LINC00474, AL691426.1.
- chr9:117,840,322–118,083,382, 2 genes, copy number 5 (within-gene range 4–5): AL354754.1, TPT1P9.
- chr9:120,600,811–121,050,275, 10 genes, copy number 5: MEGF9, AHCYP2, FBXW2, B3GNT10, AL161911.1, PSMD5, CUTALP, PHF19, TRAF1, C5.
- chr9:137,293,868–137,423,211, 4 genes, copy number 5: BX255925.1, BX255925.4, NRARP, EXD3.
- chr9:137,459,952–137,615,360, 5 genes, copy number 5–6: PNPLA7, MRPL41, DPH7, ZMYND19, ARRDC1.
- chr9:137,615,332–137,618,906, 1 gene, copy number 6: ARRDC1-AS1.
- chr12:57,216,794–57,619,638, 26 genes, copy number 5 (within-gene range 4–5): NXPH4, AC137834.2, SHMT2, NDUFA4L2, STAC3, AC137834.1, R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1.
- chr12:63,779,842–64,990,646, 43 genes, copy number 5 (within-gene range 4–5): RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2, AC025576.3, AC025576.2, AC025576.1, C12orf66, RNU6-1009P, AC012158.1, RNU5A-7P, C12orf56, OOEPP2, ATP6V1E1P3, AC135279.1, XPOT, AC135279.2, AC135279.3, TBK1, AC136977.1, RASSF3, AC078962.2, SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P.
- chr12:65,169,583–65,248,355, 1 gene, copy number 5 (within-gene range 4–5): LEMD3.
- chr12:65,758,020–70,443,923, 102 genes, copy number 5–8 (broad region; genes not listed).
- chr12:82,686,880–83,172,740, 4 genes, copy number 5–6: TMTC2, RNU6-977P, RPL6P25, AC090680.1.
- chr12:98,453,835–98,503,855, 2 genes, copy number 5: SLC9A7P1, LINC02453.
- chr21:13,762,338–13,777,266, 3 genes, copy number 38: FEM1AP1, AL050303.1, TERF1P1.

Autosomal genes at a single copy (total copy number 1): 1,245. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
